Surgical pathology report (de-identified scan), TCGA case TCGA-NQ-A638, project TCGA-MESO (Mesothelioma), tissue source site International Genomics Consortium, specimen TCGA-NQ-A638-01A (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

(MR# [REDACTED]) Printed by [REDACTED]

Description: r old male

Department: [REDACTED]

ED Encounter Report

Encounter Report

Transcription Result

Type
Surgical Pathology

ID

Dictating Date/Time

Author

Authenticated by [REDACTED]

Document Text

SURGERY CASE #:

FINAL

DATE OF SURGERY:

SURGEON:

SPECIMEN:

- A. Diaphragm nodule, right chest.
- B. Wedge, right lower lobe chest wall.
- C. Wedge, basilar, right lower lobe.

FROZEN SECTION DIAGNOSIS:

- A. Malignant neoplasm.
- B. Surgical margins free of tumor.
- C. Malignant neoplasm.

OPERATIVE PROCEDURE:

possible thoracotomy, possible
possible chest wall resection.

Right video-assisted thoracoscopy,
lobectomy,

PREOPERATIVE DIAGNOSIS:

Right lung mass.

POSTOPERATIVE DIAGNOSIS:

None given.

*****DIAGNOSIS*****

A,B,C:

1. Type of specimen:
Right lower lobe wedge with chest wall resection, diaphragmatic
nodule right chest and wedge basilar right lower lobe.
2. Tumor histologic type and grade:
Malignant mesothelioma, predominantly epithelial type, moderately
differentiated.
3. Tumor size:
Multiple tumor nodules ranging from 6.0 cm to 0.5 cm maximally.
4. Extent of invasion:
Multiple tumor nodules involving pleura, lung and diaphragmatic
muscle.
5. Lymphatic (small vessel) invasion:
Absent.
6. Venous (large vessel) invasion:
Absent.
7. Surgical margins:
All surgical margins free of tumor.
8. TNM staging: pT2, pNX, pMX
88331, 88307, 88342, 88342, 88342, 88342, 88342, 88331, 88332,
88332, 88332, 88311, 88309,
88331, 88307

Mesothelioma, NOS
Site: Pleura NOS
9/10/13
9850/3
038.4

[page 2 of 3]
MICROSCOPIC EXAMINATION:

- A. Sections are of diaphragm with a malignant epithelial neoplasm with a tubulopapillary growth pattern. The cells demonstrate moderate to abundant amount of cytoplasm with enlarged round nuclei with irregularly clumped chromatin pattern and small, but prominent nucleoli with mitotic activity seen. No definite lymphovascular invasion is seen. Immunohistochemistry stains are obtained and the neoplastic cells are strongly positive with calretinin, strongly positive with cytokeratin5, positive with cytokeratin7, negative with cytokeratin20, negative with Napsin A, negative with TTF-1 and shows strong nuclear staining with WT-1. The tumor is seen involving the diaphragmatic muscle.
- B. Multiple sections are examined, and sections from the soft tissue surgical margins are free of tumor. Sections of the parenchymal lung surgical margin is also free of tumor. Sections of the neoplasm grossly described demonstrates a tumor with a predominantly tubular growth pattern demonstrating similar morphology as previously described in specimen A. In areas a papillary growth pattern is also noted. There is no definite lymphovascular invasion. There is a minor spindle cell component identified, and the tumor is pleural based focally involving the lung parenchyma. The separate nodule present in the pleura demonstrates malignancy with similar features. The additional smaller nodule present in the lung also demonstrates similar morphology. Random sections taken from the grossly uninvolved lung demonstrates no significant fibrosis or significant inflammation. Sections of the ribs including the rib adjacent to the tumor demonstrates no intramedullary involvement by tumor. A focus of neoplasm present in the adjacent soft tissue. The marrow demonstrates myeloid and erythroid precursors with megakaryocytes. Sections of the rib surgical margins are free of tumor.
- C. Sections are of lung parenchyma with a subpleural tumor demonstrating similar histology as described above with tumor extending to, but not through, the ink pleural surface. Sections of the grossly uninvolved lung demonstrate focal minimal chronic inflammation but no significant fibrosis.

GROSS:

- A. Received in Formalin labeled with the patient's name, account number, and "diaphragm nodule, right chest" is a single fragment of pink-tan tissue measuring 1.3 x 1.2 x 0.6 cm. The specimen is bisected to reveal a pale tan, homogeneous interior. Representative sections are submitted for frozen section and following permanent sections in Cassette #1, with touch preparations also performed. The remainder is totally submitted in block #2 for permanent. TS-2
- B. Received fresh labeled "wedge, right lower lobe chest wall" is a 7 x 5 x 3 cm in maximum dimensions wedge resection of lung with staple line and chest wall resection, including ribs and soft tissue measuring 10 x 7.5 x 2 cm. There is grossly a tumor that appears to be pleural-based, extending into the lung parenchyma, with the tumor measuring up to 6 cm maximally. A separate nodule that also appears pleural-based is identified measuring 0.9 cm. The tumor is at least 1 cm from the rib and soft tissue surgical margins, and at least 1 cm from the parietal pleural margin. The tumor is within 3 cm from the parenchymal lung surgical margin. On cut surface, as previously described, the tumor appears to be pleural-based, and attached to the lung, but not involving the parenchyma. The tumor appears to be grossly approaching, but not involving, the underlying periosteum of the rib, and the rib surgical margins appear grossly free of tumor. A small additional subpleural nodule is present in the wedge of the lung that measures 0.5 cm maximally. Representative section of the tumor is submitted for Genomics Project and chemosensitivity studies. Sections are submitted for frozen section and frozen section

[page 3 of 3]
diagnosis as follows: Cassette #1 - Anterior and superior soft tissue surgical margins with superior margin inked in black. #2 - Posterior and inferior surgical margins with inferior margin inked in black. #3 - Parietal pleural margin. #4 - Parenchymal surgical margin. Sections are then submitted for permanent as follows: #5 through #9 - Sections of tumor. #10 - Additional pleural-based nodule. #11 - Additional subpleural nodule present in wedge of lung. #12 - Random sections of grossly uninvolved lung. #13 - Sections of periosteum and rib adjacent to tumor. #14 - Anterior rib surgical margins. #15 - Posterior rib surgical margins with #13, #14, and #15 submitted after decalcification. [REDACTED]

- C. Received fresh labeled with the patient's name, account number, and "basilar wedge, right lower lobe" is a wedge biopsy of lung measuring 5.5 x 1.5 x 1.5 cm. The pleural surface is red-tan and focally white. The pleural surface is inked in black. Sectioning reveals a white-tan firm area measuring 1.7 cm maximally on the pleural surface. Representative sections are submitted for frozen section and following permanent sections in Cassette #1, with touch preparations also performed. Additional sections are submitted for permanent in blocks #2 and #3, with block #3 containing normal lung. RS-3 [REDACTED]

Electronically Signed by

[REDACTED] MD

[REDACTED] MD

Dictated: Job#
Transcribed: Doc# [REDACTED] on

cc: [REDACTED]

Transcription
History Transcription History

Service
Date/Time
Filed
Date/Time

Treatment Team Report
All Treatment Team for Encounter

MR # [REDACTED] CSN # [REDACTED]

Source: NCI Genomic Data Commons file cfa8de81-20e0-48e7-bc59-4cb340d45884 (TCGA-NQ-A638.0B036FC7-E7AE-49D1-A5C6-C93D41C98C6D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).